Somatic mutation profile of tumor specimen TCGA-F2-A44H-01A (aliquot TCGA-F2-A44H-01A-11D-A26I-08) from TCGA case TCGA-F2-A44H, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.7 years (24,007 days).
Specimen TCGA-F2-A44H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef100a91-8220-45ec-a956-145b6c8af71b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F2-A44H-10A (Blood Derived Normal), aliquot TCGA-F2-A44H-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/237c00aa-64a9-403f-aa4c-aa40b1f1941a

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 10, Silent 6, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGGF1 | c.1571A>T p.D524V | Missense Mutation (SNP) | VAF 60/756 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.189); catalogued as COSV100461936; called by muse, mutect2
- ALPK2 | c.135G>A p.W45* | Nonsense Mutation (SNP) | VAF 39/268 reads (15%) | catalogued as COSV100864466; called by muse, mutect2, varscan2
- APLF | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 134/985 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100376765; called by muse, mutect2, varscan2
- ASH2L | c.844A>T p.N282Y | Missense Mutation (SNP) | VAF 37/388 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.365); catalogued as COSV99166992; called by muse, mutect2
- CATSPERD | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 147/1461 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV101062619; called by muse, mutect2, varscan2
- MLF2 | c.610C>T p.R204W | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs973096788, COSV52571255; called by muse, mutect2
- MYH7 | c.4864C>G p.L1622V | Missense Mutation (SNP) | VAF 96/799 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV100806221; called by muse, mutect2, varscan2
- PCARE | c.1363C>A p.P455T | Missense Mutation (SNP) | VAF 30/536 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.184); catalogued as COSV100527615; called by muse, mutect2
- RBM10 | c.2356-1G>C p.X786_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100237939, COSV61308693; called by muse, mutect2, varscan2
- RRP8 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.625); catalogued as COSV99601938; called by muse, mutect2
- SORT1 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99860845; called by muse, mutect2, varscan2
- TRIM37 | c.416A>T p.H139L | Missense Mutation (SNP) | VAF 50/882 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99233070; called by muse, mutect2
- BST2 | c.339G>T p.V113= | Silent (SNP) | VAF 98/890 reads (11%) | catalogued as COSV99392082; called by muse, mutect2, varscan2
- LILRA6 | c.753C>T p.Y251= | Silent (SNP) | VAF 38/641 reads (6%) | catalogued as rs370378163; called by muse, mutect2
- MCM3AP | c.771G>A p.A257= | Silent (SNP) | VAF 93/792 reads (12%) | catalogued as rs957944688, COSV99387085; called by muse, mutect2, varscan2
- PXDNL | c.2676C>G p.A892= | Silent (SNP) | VAF 36/400 reads (9%) | catalogued as rs962045966, COSV100684245; called by muse, mutect2
- SYNE1 | c.14346A>G p.E4782= (on ENST00000367255 / NM_182961.4; = p.E4711= on NM_033071.3) | Silent (SNP) | VAF 14/346 reads (4%) | catalogued as COSV99567660; called by muse, mutect2
- ZNF484 | c.333A>G p.P111= | Silent (SNP) | VAF 99/619 reads (16%) | catalogued as COSV100214713; called by muse, mutect2, varscan2
